Somatic mutation profile of cancer-model specimen HCM-CSHL-0242-C18-85A (3D Organoid; aliquot HCM-CSHL-0242-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0242-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.1 years (26,343 days).
Specimen HCM-CSHL-0242-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaed764f-db30-485b-ba98-c2ce1d27cd4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0242-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0242-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5f710a2-ea07-4e98-b6c9-5cf73d49e136

The open-access MAF lists 2,662 somatic variants for this specimen: 1,799 protein-altering or splice-affecting, 503 silent, 360 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,253, Silent 503, Frame Shift Del 355, Intron 191, Frame Shift Ins 78, 5'UTR 43, 3'UTR 43, Nonsense Mutation 36, RNA 36, Splice Region 32, 5'Flank 26, Splice Site 25.

Variants (750 of 2,662; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 115/226 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.352); catalogued as rs746800707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 112/395 reads (28%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AIRE | c.1103dup p.L370Afs*2 | Frame Shift Ins (INS) | VAF 121/305 reads (40%) | catalogued as rs387906293; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 87/233 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/475 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A5 | c.1376del p.P459Qfs*15 | Frame Shift Del (DEL) | VAF 73/102 reads (72%) | catalogued as rs104886113, CD961911; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 36/64 reads (56%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MMP2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 85/170 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs121912953, CM012155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 232/456 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs397516135, HM0650, COSV62519421; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NAGLU | c.648del p.S217Pfs*22 | Frame Shift Del (DEL) | VAF 186/469 reads (40%) | catalogued as rs760370189; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 48/113 reads (42%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RSPH1 | c.680dup p.P228Afs*15 | Frame Shift Ins (INS) | VAF 126/358 reads (35%) | catalogued as rs556286752; ClinVar: pathogenic; called by pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 103/206 reads (50%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 271/565 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 160/361 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 86/178 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326753, COSV59327496; called by muse, mutect2, varscan2
- A2ML1 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755702632, COSV55289544; called by muse, mutect2, varscan2
- AACS | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780717330; called by muse, mutect2, varscan2
- AADAC | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as rs146809751; called by muse, mutect2, varscan2
- ABCA12 | c.6739G>A p.G2247S (on ENST00000272895 / NM_173076.3; = p.G1929S on NM_015657.3) | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55972901; called by muse, mutect2, varscan2
- ABCA13 | c.6205C>A p.L2069I | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV70033729; called by muse, mutect2, varscan2
- ABCA3 | c.4834C>T p.R1612W | Missense Mutation (SNP) | VAF 299/644 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs748547109; called by muse, mutect2, varscan2
- ABCC4 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759564295, COSV65313323; called by muse, mutect2, varscan2
- ABHD2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61776627; called by muse, varscan2
- ABHD2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs374166259; called by muse, varscan2
- ABLIM1 | c.1934-1G>T p.X645_splice | Splice Site (SNP) | VAF 74/182 reads (41%) | catalogued as COSV53302209; called by muse, mutect2, varscan2
- AC013477.1 | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53653975; called by muse, mutect2, varscan2
- AC244197.3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs369603623, COSV61712782; called by muse, mutect2, varscan2
- AC244197.3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs782445506; ClinVar: benign; called by muse, mutect2, varscan2
- ACAN | c.4594G>A p.E1532K | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.914); catalogued as rs755141817; called by muse, mutect2, varscan2
- ACAP1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs757055997; called by muse, mutect2
- ACSF3 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 221/445 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58076568; called by muse, mutect2, varscan2
- ACTL9 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1555753452, COSV61005115; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 107/119 reads (90%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS19 | c.1782C>A p.C594* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99178851; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140237789; called by muse, mutect2, varscan2
- ADAR | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as rs747462052, COSV99425769; called by muse, mutect2, varscan2
- ADCY10 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183008856; called by muse, mutect2, varscan2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 140/253 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- ADGRB2 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748743741; called by muse, mutect2, varscan2
- ADGRB2 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1002859055, COSV57078563; called by muse, mutect2, varscan2
- ADGRB3 | c.2498C>T p.T833M | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV53257399, COSV53258820; called by muse, mutect2, varscan2
- ADGRE2 | c.2218A>G p.I740V | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.921); catalogued as rs758592313; called by muse, mutect2, varscan2
- ADORA2A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 111/207 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs201181215; called by muse, mutect2, varscan2
- AFF2 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99667068; called by muse, mutect2, varscan2
- AGMAT | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.563); catalogued as rs377410185; called by mutect2, varscan2
- AGTR2 | c.419T>G p.V140G | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV64157021; called by muse, mutect2, varscan2
- AHDC1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs766550931; called by muse, mutect2, varscan2
- AKAP13 | c.7608+4C>T | Splice Region (SNP) | VAF 83/195 reads (43%) | catalogued as rs765320866; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 328/354 reads (93%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKR1C8P | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs782390528; called by muse, mutect2
- AL136295.1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1037307556; called by muse, mutect2, varscan2
- AL645922.1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 30/579 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.097); catalogued as COSV100190655; called by muse, mutect2
- ALDH18A1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 208/445 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1183327194; called by muse, mutect2, varscan2
- AMBRA1 | c.1067C>T p.S356L (on ENST00000458649 / NM_001367468.1; = p.S266L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.143); catalogued as rs144750570; called by muse, mutect2, varscan2
- AMPD2 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs141742198; called by muse, mutect2, varscan2
- ANGEL1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs775354721, COSV51873019; called by muse, mutect2, varscan2
- ANKH | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 193/436 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.542); catalogued as rs1190164920, COSV52479201; called by muse, mutect2, varscan2
- ANKLE1 | c.69del p.E24Sfs*54 | Frame Shift Del (DEL) | VAF 100/260 reads (38%) | catalogued as rs139615873; called by mutect2, pindel, varscan2
- ANKRD13B | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 164/361 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs769516438; called by muse, mutect2, varscan2
- ANKRD13C | c.211A>G p.N71D | Missense Mutation (SNP) | VAF 102/190 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as rs1291258023; called by muse, mutect2, varscan2
- ANKRD65 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 163/309 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1410096668; called by muse, mutect2, varscan2
- ANO2 | c.464G>A p.R155Q (on ENST00000356134 / NM_001278597.3; = p.R159Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 110/201 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs746661048; called by muse, mutect2, varscan2
- ANXA13 | c.451dup p.I151Nfs*9 | Frame Shift Ins (INS) | VAF 76/171 reads (44%) | catalogued as rs759218332; called by mutect2, varscan2
- AP3D1 | c.2581_2586del p.K861_K862del | In Frame Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs1325272641; called by mutect2, pindel
- AP3M1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs541963645; called by muse, mutect2, varscan2
- APBA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762371853, COSV55227236; called by muse, mutect2, varscan2
- APBA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs564159274, COSV55232051; called by muse, mutect2, varscan2
- APC | c.1264del p.E422Sfs*32 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | catalogued as CM106640, CX056897, COSV104378826; called by mutect2, pindel, varscan2
- APC2 | c.6205G>A p.G2069S | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1391507735; called by muse, mutect2, varscan2
- APOBEC3F | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1408166368; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 82/192 reads (43%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- AQP7 | c.189del p.K63Nfs*31 | Frame Shift Del (DEL) | VAF 65/179 reads (36%) | catalogued as COSV53008175; called by mutect2, pindel, varscan2
- ARFGAP2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1342213501; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 47/113 reads (42%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF3 | c.4966G>A p.A1656T | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as COSV99294786; called by muse, mutect2
- ARHGAP35 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68336836; called by muse, mutect2, varscan2
- ARHGEF12 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34726241; called by muse, mutect2, varscan2
- ARHGEF40 | c.3820C>T p.H1274Y | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as COSV53879668; called by muse, mutect2, varscan2
- ARL10 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 128/283 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV53798213; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 85/160 reads (53%) | catalogued as rs753865255; called by mutect2, varscan2
- ASAP2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55631989; called by muse, mutect2, varscan2
- ASNS | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 116/190 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51555665; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 117/215 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ASPRV1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as rs749880547, COSV100208468; called by muse, varscan2
- ATAD3C | c.512G>T p.R171M | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66483228, COSV66483318; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATG16L2 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 115/223 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770072481; called by muse, mutect2, varscan2
- ATG2A | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773884095; called by muse, mutect2, varscan2
- ATP13A2 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as rs764988645, COSV58700082; called by muse, mutect2, varscan2
- ATP2A2 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 122/232 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1352765498; called by muse, mutect2, varscan2
- ATP2B4 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 153/347 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779972851, COSV58174463; called by muse, mutect2, varscan2
- ATP2C1 | c.75del p.A26Qfs*21 | Frame Shift Del (DEL) | VAF 118/274 reads (43%) | catalogued as rs1559936852, COSV60757077; called by mutect2, pindel, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 28/52 reads (54%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- AXIN2 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 212/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747647668, COSV61059552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT6 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55420101; called by mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 101/215 reads (47%) | catalogued as rs35951843; called by mutect2, varscan2
- BAIAP3 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1056198053; called by muse, mutect2, varscan2
- BARHL2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 16/525 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1312809958, COSV64980950; called by muse, mutect2
- BCL2 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV61386068; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 70/144 reads (49%) | catalogued as rs752427670; called by mutect2, varscan2
- BICD2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs778940849; called by muse, mutect2, varscan2
- BICRA | c.1320del p.A442Pfs*2 | Frame Shift Del (DEL) | VAF 51/133 reads (38%) | catalogued as rs1361394574; called by mutect2, pindel, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 128/324 reads (40%) | catalogued as rs758822270; called by mutect2, varscan2
- BMP15 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as rs781848548, COSV53140331; called by muse, mutect2, varscan2
- BOP1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1435772457; called by muse, mutect2, varscan2
- BPIFB3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs777030919; called by muse, mutect2, varscan2
- BPNT1 | c.911del p.N304Mfs*20 | Frame Shift Del (DEL) | VAF 58/147 reads (39%) | catalogued as rs1210209988; called by mutect2, pindel, varscan2
- BRD4 | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1456519129; called by muse, mutect2, varscan2
- BRMS1L | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1023777427, COSV53762371; called by muse, mutect2, varscan2
- C10orf71 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 131/319 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV60507301; called by muse, mutect2, varscan2
- C1QTNF4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 171/357 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100209256; called by muse, mutect2, varscan2
- C1orf174 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 261/552 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as rs751234275, COSV100851824; called by muse, mutect2, varscan2
- C1orf210 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV70682505; called by muse, mutect2, varscan2
- C2orf81 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99292499; called by muse, mutect2, varscan2
- C3 | c.304del p.R102Afs*5 | Frame Shift Del (DEL) | VAF 83/221 reads (38%) | catalogued as CM940211, COSV99836473; called by mutect2, pindel, varscan2
- C3 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 243/477 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV55571750; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 35/99 reads (35%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C3orf80 | c.374del p.G125Afs*61 | Frame Shift Del (DEL) | VAF 43/84 reads (51%) | catalogued as rs775962517; called by mutect2, pindel, varscan2
- C5orf22 | c.772del p.S258Qfs*31 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs751259551; called by mutect2, varscan2
- C6orf118 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs140022567, COSV57817681; called by muse, mutect2, varscan2
- C6orf132 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1321277113, COSV59375727; called by muse, mutect2, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 81/173 reads (47%) | catalogued as rs750735753; called by mutect2, pindel, varscan2
- CACFD1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs782205792, COSV52468775; called by muse, mutect2, varscan2
- CACNA1B | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs890458453; called by muse, mutect2, varscan2
- CACNA1H | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs574809183; called by muse, mutect2, varscan2
- CAD | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779056625, COSV53024811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMTA1 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs765363667; called by muse, mutect2, varscan2
- CAPN15 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1458886277; called by muse, mutect2, varscan2
- CARD10 | c.1578dup p.S527Qfs*11 | Frame Shift Ins (INS) | VAF 24/56 reads (43%) | catalogued as rs35832225; called by mutect2, varscan2
- CARD14 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.62); catalogued as rs965855312; called by muse, mutect2
- CASP10 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53780656; called by muse, mutect2, varscan2
- CASP4 | c.128del p.K43Rfs*37 | Frame Shift Del (DEL) | VAF 119/311 reads (38%) | catalogued as rs772291949; called by mutect2, pindel, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 77/169 reads (46%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP8 | c.1063T>G p.F355V (on ENST00000432109 / NM_033355.3; = p.F372V on NM_001228.4) | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51847031; called by muse, mutect2, varscan2
- CCDC166 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs781966060; called by muse, mutect2, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 87/252 reads (35%) | catalogued as rs751612825; called by pindel, varscan2
- CCDC185 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 144/296 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as rs1173730581, COSV64822056; called by muse, mutect2, varscan2
- CCDC40 | c.2519T>C p.L840P | Missense Mutation (SNP) | VAF 205/419 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66473010; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC66 | c.254del p.N85Mfs*3 (on ENST00000394672 / NM_001353147.1; = p.N51Mfs*3 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 96/214 reads (45%) | catalogued as rs751844604; called by mutect2, varscan2
- CCDC70 | c.151dup p.I51Nfs*72 | Frame Shift Ins (INS) | VAF 92/189 reads (49%) | catalogued as rs752919705; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 56/126 reads (44%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC96 | c.973_975del p.K325del | In Frame Del (DEL) | VAF 56/104 reads (54%) | catalogued as rs1463309934; called by mutect2, pindel, varscan2
- CCDC9B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.855); catalogued as rs1345259734, COSV66876545; called by muse, mutect2, varscan2
- CCER1 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1484068156; called by muse, mutect2, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCL5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1482072962; called by muse, mutect2, varscan2
- CCNG2 | c.890del p.G297Vfs*15 | Frame Shift Del (DEL) | VAF 64/170 reads (38%) | catalogued as rs745928364; called by mutect2, pindel, varscan2
- CCP110 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs370713605; called by muse, mutect2, varscan2
- CCT3 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs1455894708; called by muse, mutect2, varscan2
- CCT4 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs768770405; called by muse, mutect2, varscan2
- CD276 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 117/261 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs755716069, COSV59202970; called by muse, mutect2, varscan2
- CDCA4 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1431299150; called by muse, mutect2, varscan2
- CDH7 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs780536938, COSV59885635; called by muse, mutect2, varscan2
- CDKN2AIP | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs747819772, COSV56626841; called by muse, mutect2, varscan2
- CDSN | c.1530del p.Q512Sfs*2 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs756296748; called by mutect2, pindel, varscan2
- CELF5 | c.102del p.Q35Sfs*5 | Frame Shift Del (DEL) | VAF 106/308 reads (34%) | catalogued as COSV53011441; called by mutect2, pindel, varscan2
- CELSR1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs752239073, COSV53088286; called by muse, mutect2, varscan2
- CELSR2 | c.5282G>A p.C1761Y | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs927238797; called by muse, mutect2, varscan2
- CEP104 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs763300107, COSV58214912; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 102/199 reads (51%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP41 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 189/601 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200709703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP63 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1235488221; called by muse, mutect2, varscan2
- CEP85 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 111/212 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs779280111, COSV53330615; called by muse, mutect2, varscan2
- CES5A | c.1624A>G p.T542A (on ENST00000290567 / NM_001143685.2; = p.T492A on NM_145024.3) | Missense Mutation (SNP) | VAF 243/509 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as rs1262275161, COSV51871382; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 106/279 reads (38%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP74 | c.4352A>G p.Y1451C | Missense Mutation (SNP) | VAF 182/393 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs750094787; called by muse, mutect2, varscan2
- CFHR5 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56823704; called by muse, mutect2, varscan2
- CGN | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006810957, COSV99642139; called by muse, mutect2, varscan2
- CGN | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368607138; called by muse, mutect2, varscan2
- CHD2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101244912; called by muse, mutect2, varscan2
- CHD3 | c.3660G>A p.M1220I | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as COSV57878563; called by muse, mutect2, varscan2
- CHPF2 | c.1941_1942insA p.S648Ifs*6 | Frame Shift Ins (INS) | VAF 91/168 reads (54%) | catalogued as COSV50390137; called by mutect2, pindel, varscan2
- CHTF18 | c.365del p.P122Lfs*47 | Frame Shift Del (DEL) | VAF 50/115 reads (43%) | catalogued as rs1442529917; called by mutect2, pindel, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751344715; called by muse, mutect2, varscan2
- CLCNKB | c.656-3del | Splice Region (DEL) | VAF 132/339 reads (39%) | catalogued as rs1279574325; called by mutect2, pindel, varscan2
- CLDN10 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 445/677 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs760145374; called by muse, mutect2, varscan2
- CLPTM1 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs762373873; called by muse, mutect2, varscan2
- CLU | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 138/283 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201024088; called by muse, mutect2, varscan2
- CMKLR1 | c.475G>A p.A159T (on ENST00000312143 / NM_001142344.2; = p.A157T on NM_004072.3) | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV56439546; called by muse, mutect2, varscan2
- CMTM2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 107/228 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778788831, COSV51748146; called by muse, mutect2, varscan2
- CNTN6 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610791; called by muse, mutect2, varscan2
- CNTNAP4 | c.2700G>T p.Q900H | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs533617576; called by muse, mutect2, varscan2
- COL18A1 | c.1124del p.G375Afs*164 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | catalogued as rs528991245; called by mutect2, varscan2
- COL23A1 | c.732C>T p.G244= | Splice Region (SNP) | VAF 126/286 reads (44%) | catalogued as rs1193637344, COSV66787362; called by muse, mutect2, varscan2
- COL27A1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs571516072, COSV61925825; called by muse, mutect2, varscan2
- COL6A2 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56004492; called by muse, mutect2
- COL7A1 | c.8018C>A p.P2673H | Missense Mutation (SNP) | VAF 210/455 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56476922; called by muse, mutect2, varscan2
- COL7A1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772888814, COSV60391197; called by muse, mutect2, varscan2
- COLEC12 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs200501360; called by muse, mutect2, varscan2
- COPA | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138441444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 162/348 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs182487045, COSV56694512; called by muse, mutect2, varscan2
- CPAMD8 | c.272G>A p.G91D (on ENST00000651564; = p.G44D on NM_015692.5) | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52232320; called by muse, mutect2, varscan2
- CPQ | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753340797, COSV55140372; called by muse, mutect2, varscan2
- CPSF6 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 54/108 reads (50%) | catalogued as COSV99879541; called by muse, mutect2, varscan2
- CR2 | c.734+2T>C p.X245_splice | Splice Site (SNP) | VAF 156/338 reads (46%) | catalogued as rs771175429; called by muse, mutect2, varscan2
- CRACDL | c.1565del p.P522Rfs*182 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs1414963793; called by mutect2, pindel, varscan2
- CRB2 | c.612C>T p.N204= | Splice Region (SNP) | VAF 53/109 reads (49%) | catalogued as rs570941986, COSV63504628; called by muse, mutect2, varscan2
- CROCC | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752953125; called by muse, mutect2, varscan2
- CROCC | c.5519G>A p.R1840Q | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs996889794, COSV100977599; called by muse, mutect2, varscan2
- CRYBG3 | c.8389G>A p.A2797T | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV99477083; called by muse, mutect2
- CSMD3 | c.2501G>A p.C834Y (on ENST00000297405 / NM_001363185.1; = p.C730Y on NM_052900.3) | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52345312; called by muse, mutect2, varscan2
- CSNK1G2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs758407129; called by muse, mutect2, varscan2
- CSPG4 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367600030; called by muse, varscan2
- CSRNP1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781483967; called by mutect2, varscan2
- CST11 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs756302384, COSV63140192; called by muse, mutect2, varscan2
- CTDSPL2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs779587261, COSV52948373; called by muse, mutect2, varscan2
- CUL2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66081586; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs772257590; called by mutect2, varscan2
- CYP2E1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs76138620; called by muse, mutect2, varscan2
- CYP3A7 | c.644C>A p.P215Q | Missense Mutation (SNP) | VAF 186/581 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV60481380; called by muse, mutect2, varscan2
- CYP4F3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs774751788, COSV99657972; called by muse, mutect2, varscan2
- DCST1 | c.174del p.L59Sfs*4 | Frame Shift Del (DEL) | VAF 90/251 reads (36%) | catalogued as rs746224810; called by mutect2, pindel, varscan2
- DDIT4L | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56767166; called by muse, mutect2, varscan2
- DDX10 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs774783994, COSV59431123; called by muse, mutect2, varscan2
- DDX31 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 135/259 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257083396; called by muse, mutect2, varscan2
- DFFA | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755323383; called by muse, mutect2, varscan2
- DHDH | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 110/217 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs772545415, COSV55481986; called by muse, mutect2, varscan2
- DHX16 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 189/419 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs749340666; called by muse, mutect2, varscan2
- DHX37 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764894461; called by muse, mutect2, varscan2
- DISC1 | c.1946T>C p.L649P | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1350953507; called by muse, mutect2, varscan2
- DLEU7 | c.94del p.D32Tfs*59 | Frame Shift Del (DEL) | VAF 110/208 reads (53%) | catalogued as rs867917062; called by mutect2, pindel, varscan2
- DLGAP2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs768383340; called by muse, mutect2
- DLK2 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55084236; called by muse, mutect2, varscan2
- DLL1 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs769028878, COSV64537474; called by muse, mutect2, varscan2
- DMD | c.3601A>C p.K1201Q | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1185291494; called by muse, mutect2, varscan2
- DMXL1 | c.7934C>T p.A2645V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60719530; called by muse, mutect2, varscan2
- DNAH11 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995773912; called by muse, mutect2, varscan2
- DNAH2 | c.6584G>A p.R2195H | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359336800, COSV66721621; called by muse, mutect2, varscan2
- DNAH3 | c.8306C>A p.A2769D | Missense Mutation (SNP) | VAF 165/388 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV99769443; called by muse, mutect2, varscan2
- DNAH8 | c.10495C>T p.R3499C | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758179326, COSV59469603; called by muse, mutect2, varscan2
- DNAJB14 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1183142425, COSV100508655; called by muse, mutect2, varscan2
- DOC2A | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757458777, COSV100451141, COSV58750916; called by muse, mutect2, varscan2
- DOCK9 | c.5017C>T p.R1673W (on ENST00000376460 / NM_001366676.2; = p.R1674W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/173 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as rs556673005; called by muse, mutect2, varscan2
- DOK6 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203760352; called by muse, mutect2, varscan2
- DPEP1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377182881; called by muse, mutect2, varscan2
- DPEP2 | c.120del p.R41Efs*39 | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | catalogued as rs547189498; called by mutect2, pindel, varscan2
- DPP3 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs566532784; called by muse, mutect2, varscan2
- DROSHA | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 91/185 reads (49%) | catalogued as rs749032311, COSV60782123; called by muse, mutect2, varscan2
- DSCAM | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 267/521 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV68026184; called by muse, mutect2, varscan2
- DSG2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 152/300 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as rs549421694, COSV55199599; called by muse, mutect2, varscan2
- DTX2 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 107/447 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1424306245; called by muse, varscan2
- DUSP4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as rs1236075524, COSV53546398; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 38/89 reads (43%) | catalogued as rs755197346; called by mutect2, varscan2
- EBF3 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 193/433 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs746403949; called by muse, mutect2, varscan2
- ECD | c.1179A>G p.I393M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65899787; called by muse, mutect2, varscan2
- ECI1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs773367840, COSV100066508; called by muse, varscan2
- EFCAB2 | c.669A>T p.R223S (on ENST00000366522; = p.R87S on NM_032328.3) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs1558296590; called by muse, mutect2, varscan2
- EGR2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99653917; called by muse, mutect2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | catalogued as COSV99653876; called by pindel, varscan2*
- EIF2AK2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs747429747, COSV51798081; called by muse, mutect2, varscan2
- EIF2B4 | c.1448G>A p.R483Q (on ENST00000347454 / NM_001034116.2; = p.R482Q on NM_015636.3) | Missense Mutation (SNP) | VAF 188/382 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs776097463; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs759858342; called by mutect2, varscan2
- ENG | c.771del p.Y258Tfs*101 | Frame Shift Del (DEL) | VAF 182/405 reads (45%) | catalogued as CD075380; called by mutect2, pindel, varscan2
- ENO4 | c.848C>T p.S283L (on ENST00000622726; = p.S282L on NM_001242699.2) | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1294513399; called by muse, mutect2, varscan2
- ENPP2 | c.2395C>T p.R799W (on ENST00000075322 / NM_001040092.3; = p.R851W on NM_006209.5) | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370024218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EOMES | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 306/544 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1180443168; called by muse, mutect2, varscan2
- EPHA5 | c.2411G>T p.R804I | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99901584; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 58/74 reads (78%) | catalogued as rs756461692; called by mutect2, varscan2
- EQTN | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 121/253 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1264804619; called by muse, mutect2, varscan2
- ESPNL | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs748875074; called by muse, mutect2, varscan2
- EVC | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 257/480 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756208272, COSV53838730, COSV99381347; called by muse, mutect2, varscan2
- EYA4 | c.1688C>T p.A563V (on ENST00000531901 / NM_001301013.1; = p.A557V on NM_004100.5) | Missense Mutation (SNP) | VAF 90/270 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs933456827, COSV62051444; called by muse, mutect2, varscan2
- F12 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 223/439 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1192778187; called by muse, mutect2, varscan2
- FAAP100 | c.2175C>T p.G725= | Splice Region (SNP) | VAF 49/107 reads (46%) | catalogued as rs758795190, COSV59884544; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 100/232 reads (43%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 28/64 reads (44%) | catalogued as rs756478120; called by mutect2, varscan2
- FAM110D | c.484_486del p.K162del | In Frame Del (DEL) | VAF 66/130 reads (51%) | catalogued as rs1299602440; called by mutect2, pindel, varscan2
- FAM131A | c.768del p.S257Afs*48 (on ENST00000310585; = p.S288Afs*48 on NM_144635.5) | Frame Shift Del (DEL) | VAF 82/199 reads (41%) | catalogued as COSV55602091; called by mutect2, pindel, varscan2
- FAM155A | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 102/166 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs752264469; called by muse, varscan2
- FAM160A2 | c.1948C>T p.R650C (on ENST00000449352 / NM_001098794.2; = p.R664C on NM_032127.4) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs749214656, COSV56409753; called by muse, mutect2, varscan2
- FAM187A | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs529160132, COSV53651958; called by muse, mutect2, varscan2
- FAM83F | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs189817068; called by muse, mutect2, varscan2
- FAT2 | c.11008A>G p.S3670G | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1348729434; called by muse, mutect2, varscan2
- FAT2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377056065; called by muse, mutect2, varscan2
- FAT3 | c.6787G>A p.A2263T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs777108809, COSV53071923; called by muse, mutect2
- FAT4 | c.1239A>C p.K413N | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as COSV67903778; called by muse, mutect2
- FBN2 | c.5311G>T p.A1771S | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52496391; called by muse, mutect2
- FBRS | c.976G>A p.A326T (on ENST00000287468; = p.A846T on NM_001105079.3) | Missense Mutation (SNP) | VAF 232/506 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as rs370683199, COSV99788999; called by muse, mutect2, varscan2
- FBXL14 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs1565579659; called by muse, mutect2
- FBXO40 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 91/167 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573301; called by muse, mutect2, varscan2
- FBXO43 | c.644_646del p.E215del | In Frame Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs768812568; called by pindel, varscan2
- FBXW11 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 171/330 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs1280861852, COSV51615393; called by muse, mutect2, varscan2
- FCRL4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 89/171 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.15); catalogued as rs770243398, COSV99619088; called by muse, mutect2, varscan2
- FGFR3 | c.*894G>A | Splice Region (SNP) | VAF 89/175 reads (51%) | catalogued as rs1293700770; called by muse, mutect2, varscan2
- FIGNL2 | c.668del p.P223Qfs*9 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs1222956431; called by mutect2, pindel, varscan2
- FLG2 | c.6026A>G p.H2009R | Missense Mutation (SNP) | VAF 181/347 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1366821955; called by muse, mutect2, varscan2
- FLNA | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774810; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 138/310 reads (45%) | catalogued as COSV56098414; called by mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXF2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1243463177; called by muse, varscan2
- FOXL2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 168/331 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57727727; called by muse, mutect2, varscan2
- FOXP4 | c.1235del p.P412Rfs*77 (on ENST00000307972 / NM_001012426.1; = p.P399Rfs*77 on NM_138457.3) | Frame Shift Del (DEL) | VAF 64/166 reads (39%) | catalogued as COSV57223583; called by mutect2, pindel, varscan2
- FRMD3 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 36/85 reads (42%) | catalogued as COSV100418512; called by muse, mutect2, varscan2
- FRMD6 | c.1436T>C p.M479T (on ENST00000344768 / NM_001267046.2; = p.M471T on NM_152330.4) | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs752504588; called by muse, mutect2, varscan2
- FRRS1L | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1411339072, COSV73746922; called by muse, mutect2, varscan2
- FURIN | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 111/204 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176003081, COSV51574849; called by muse, mutect2, varscan2
- FUT1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 176/325 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs541722036, CM1111181, COSV59569245; called by muse, mutect2, varscan2
- FYCO1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138529231; called by muse, mutect2, varscan2
- FZD8 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 154/285 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65968487; called by muse, mutect2, varscan2
- GABBR1 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 110/216 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.499); catalogued as rs1243700899, COSV63542877; called by muse, mutect2, varscan2
- GABRB3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV54683394; called by muse, mutect2, varscan2
- GAL3ST2 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 122/249 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV51951098; called by muse, mutect2, varscan2
- GALNTL5 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101218030, COSV67179543; called by muse, mutect2, varscan2
- GAS6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs747484336; called by muse, varscan2
- GATA2 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV62006102; called by muse, mutect2, varscan2
- GATA5 | c.248del p.P83Qfs*64 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | catalogued as rs1555897019; called by mutect2, varscan2
- GBP5 | c.692del p.K231Rfs*26 | Frame Shift Del (DEL) | VAF 82/211 reads (39%) | catalogued as rs767245260; called by mutect2, pindel, varscan2
- GCN1 | c.6289C>A p.L2097I | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56113451; called by muse, mutect2, varscan2
- GDF1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs868299849; called by muse, mutect2, varscan2
- GDF2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1555208722; called by muse, mutect2, varscan2
- GEMIN5 | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768763545, COSV99594234; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA5 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 212/411 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs782580208, COSV54785362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 220/691 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270096533; called by muse, mutect2, varscan2
- GLIS3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1277705225; called by muse, mutect2
- GLIS3 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs746828453, COSV60930958; called by muse, mutect2, varscan2
- GOLGA2 | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs1299206643; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 68/127 reads (54%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLPH3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1295953441, COSV54061389; called by muse, mutect2, varscan2
- GPALPP1 | c.969del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 86/352 reads (24%) | catalogued as rs1566086213; called by mutect2, pindel, varscan2
- GPATCH8 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV59192885; called by muse, mutect2, varscan2
- GPBP1 | c.66G>A p.S22= | Splice Region (SNP) | VAF 28/48 reads (58%) | catalogued as rs369233611; called by muse, mutect2, varscan2
- GPR132 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs753534917, COSV61678008; called by muse, mutect2, varscan2
- GPR19 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as rs1475304814; called by muse, mutect2, varscan2
- GPR39 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs750566310, COSV100258105; called by muse, mutect2, varscan2
- GPR6 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 143/278 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV51573229; called by muse, mutect2, varscan2
- GPX5 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 198/409 reads (48%) | catalogued as COSV69079411; called by muse, mutect2, varscan2
- GSC | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs772555300; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554532534; called by mutect2, varscan2
- GTF3C4 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs773416400; called by muse, mutect2, varscan2
- H4C6 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV66685728; called by muse, mutect2, varscan2
- HAS1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1478264163; called by muse, mutect2, varscan2
- HAS3 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.095); catalogued as rs779896003; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 98/246 reads (40%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HCFC1 | c.3518C>T p.A1173V | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782596644; called by muse, mutect2, varscan2
- HDAC7 | c.80G>A p.R27H (on ENST00000427332; = p.R66H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs866092952, COSV99315591; called by muse, mutect2, varscan2
- HHATL | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs746586026, COSV60040810; called by muse, mutect2, varscan2
- HIC1 | c.1165G>A p.A389T (on ENST00000322941 / NM_001098202.1; = p.A370T on NM_006497.4) | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs749428578; called by muse, mutect2, varscan2
- HIRA | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54277132; called by muse, mutect2, varscan2
- HIVEP3 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.142); catalogued as rs147665727; called by muse, mutect2, varscan2
- HK3 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV52843558; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 44/90 reads (49%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPC | c.467C>T p.S156L (on ENST00000420743; = p.S143L on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60145066; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXD11 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.385); catalogued as rs544796078, COSV50910521; called by muse, mutect2, varscan2
- HRAS | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV54241530; called by muse, mutect2, varscan2
- HS2ST1 | c.522_524del p.Y175del | In Frame Del (DEL) | VAF 34/88 reads (39%) | catalogued as rs779877914; called by pindel, varscan2
- HSD3B7 | c.543del p.L182Cfs*4 | Frame Shift Del (DEL) | VAF 175/428 reads (41%) | catalogued as COSV52682172; called by mutect2, pindel, varscan2
- HTR1A | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 132/266 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60501887; called by muse, mutect2, varscan2
- HTRA3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs141190260; called by muse, mutect2, varscan2
- IGFBP3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772535932, COSV51872075; called by muse, mutect2, varscan2
- IGFBP7 | c.102del p.C35Afs*54 | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | catalogued as rs1362989660; called by mutect2, pindel, varscan2
- IGFN1 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV104403032; called by muse, mutect2, varscan2
- IGSF8 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs368177176; called by muse, mutect2, varscan2
- IGSF9 | c.2582C>T p.A861V (on ENST00000368094 / NM_001135050.2; = p.A845V on NM_020789.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1022844768; called by muse, mutect2
- IL16 | c.3143C>T p.S1048L (on ENST00000302987 / NM_172217.5; = p.S347L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57268538; called by muse, mutect2, varscan2
- ING1 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV58166979; called by muse, mutect2
- IP6K3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 170/347 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376369600; called by muse, mutect2, varscan2
- IQCH | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1289802075; called by muse, mutect2, varscan2
- IQGAP1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs773706434; called by muse, mutect2, varscan2
- IRS1 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748385460; called by muse, mutect2, varscan2
- IRX3 | c.1113del p.S372Lfs*151 | Frame Shift Del (DEL) | VAF 49/137 reads (36%) | catalogued as rs759120276; called by mutect2, pindel, varscan2
- ISYNA1 | c.416-3del | Splice Region (DEL) | VAF 33/91 reads (36%) | catalogued as rs764100802; called by mutect2, pindel, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 58/133 reads (44%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel
- ITGA7 | c.803-5del | Splice Region (DEL) | VAF 112/270 reads (41%) | catalogued as rs1346460062; called by mutect2, pindel, varscan2
- ITGAE | c.1801del p.L601Wfs*82 | Frame Shift Del (DEL) | VAF 158/401 reads (39%) | catalogued as rs867709180; called by mutect2, pindel, varscan2
- ITGB4 | c.3368del p.P1123Lfs*37 | Frame Shift Del (DEL) | VAF 120/294 reads (41%) | catalogued as rs1441262033; called by mutect2, pindel, varscan2
- ITPR2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1473494292, COSV67273903; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 145/464 reads (31%) | catalogued as rs763250381; called by mutect2, varscan2
- JMJD4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 276/604 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs549100036, COSV59919251; called by muse, mutect2, varscan2
- KANK3 | c.1177dup p.A393Gfs*110 | Frame Shift Ins (INS) | VAF 107/273 reads (39%) | catalogued as rs752726345; called by mutect2, pindel, varscan2
- KAT6A | c.4417G>C p.D1473H | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750883642, COSV99704310; called by muse, mutect2, varscan2
- KAT7 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1475495401; called by muse, mutect2, varscan2
- KAT8 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs759640339; called by muse, mutect2, varscan2
- KBTBD11 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 197/375 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs541540802, COSV57223969; called by muse, mutect2, varscan2
- KCNA5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs763338488; called by muse, mutect2, varscan2
- KCNH2 | c.1946-8G>A | Splice Region (SNP) | VAF 25/71 reads (35%) | catalogued as rs1384850938; called by muse, mutect2
- KCNH3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 146/272 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs141408790, COSV57790082; called by muse, mutect2, varscan2
- KCNJ13 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs17857137; called by muse, mutect2, varscan2
- KCNQ2 | c.1955del p.P652Rfs*278 (on ENST00000359125 / NM_172107.4; = p.P624Rfs*278 on NM_004518.6) | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | catalogued as COSV60550914; called by mutect2, pindel, varscan2
- KCNS1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747780284; called by muse, mutect2, varscan2
- KCNS3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1373662542, COSV58406105; called by muse, mutect2, varscan2
- KCNT1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 180/380 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs751166469; called by muse, mutect2, varscan2
- KDM4A | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs190275733, COSV64959293; called by muse, mutect2, varscan2
- KDM4B | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs369063729; called by muse, mutect2, varscan2
- KDM5B | c.4600C>T p.R1534C | Missense Mutation (SNP) | VAF 130/289 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs377525543; called by muse, varscan2
- KDM5C | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 117/118 reads (99%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64763107; called by muse, mutect2, varscan2
- KDM5D | c.4330C>T p.R1444W | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs776718151; called by muse, mutect2, varscan2
- KEL | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 258/429 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs758195269; called by muse, mutect2, varscan2
- KIAA1217 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as rs1564859403; called by muse, mutect2, varscan2
- KIAA1586 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as rs1461848373; called by muse, mutect2, varscan2
- KIDINS220 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as rs763970461, COSV56750845; called by muse, mutect2, varscan2
- KIF19 | c.2104A>G p.S702G | Missense Mutation (SNP) | VAF 84/154 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs939466345; called by muse, mutect2, varscan2
- KIF26A | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59464613; called by muse, mutect2, varscan2
- KIF5A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 163/400 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs780433858; called by muse, mutect2, varscan2
- KIR2DL1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 206/508 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs866902036, COSV99383502; called by muse, varscan2
- KIRREL3 | c.464del p.G155Afs*3 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs1565483272; called by mutect2, pindel, varscan2
- KL | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 176/261 reads (67%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.806); catalogued as COSV101198998; called by muse, mutect2, varscan2
- KLF10 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1345161159; called by muse, mutect2, varscan2
- KLHL14 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 124/287 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs773956260, COSV63830709; called by muse, mutect2, varscan2
- KLHL25 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs373348206; called by muse, mutect2, varscan2
- KLHL25 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs77624363; called by muse, mutect2
- KLK15 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs753651539; called by muse, mutect2, varscan2
- KRT40 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 261/538 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371375504; called by muse, mutect2, varscan2
- KRTDAP | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs746077298, COSV58865245; called by muse, mutect2, varscan2
- LAMB2 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 185/392 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs959473971; called by muse, mutect2, varscan2
- LARP1 | c.142dup p.E48Gfs*82 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs1561569092; called by mutect2, varscan2
- LBHD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs1206660934; called by muse, mutect2, varscan2
- LCA5 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs757969727; called by muse, mutect2, varscan2
- LCE1F | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 124/229 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs766315066; called by muse, mutect2, varscan2
- LCK | c.378-1G>A p.X126_splice | Splice Site (SNP) | VAF 71/139 reads (51%) | catalogued as rs1431441881; called by muse, mutect2, varscan2
- LCP2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as rs747523987, COSV50447368; called by muse, mutect2, varscan2
- LCTL | c.796del p.E266Nfs*11 | Frame Shift Del (DEL) | VAF 49/138 reads (36%) | catalogued as rs1409433509, COSV100427282; called by mutect2, pindel, varscan2
- LDHA | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 233/513 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV57039493; called by muse, mutect2, varscan2
- LDHB | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as CM930470, COSV63365566; called by muse, mutect2
- LEFTY2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 260/508 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375598455; called by muse, mutect2, varscan2
- LHCGR | c.1764dup p.A589Cfs*17 | Frame Shift Ins (INS) | VAF 218/460 reads (47%) | catalogued as rs1293879367; called by mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 41/78 reads (53%) | catalogued as rs748571616; called by mutect2, varscan2
- LILRB5 | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 69/128 reads (54%) | catalogued as COSV60255797; called by muse, mutect2, varscan2
- LINGO1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 171/362 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs746499302, COSV62437503; called by muse, mutect2, varscan2
- LITAF | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 199/431 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs753060675; called by muse, mutect2, varscan2
- LMF2 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as rs760890488; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 173/460 reads (38%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRIG3 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 125/261 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs1446034098; called by muse, mutect2, varscan2
- LRP2BP | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs111547365; called by muse, mutect2, varscan2
- LRPPRC | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs182612310, COSV99580613; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 58/141 reads (41%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC4B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs750615393, COSV101210166; called by muse, mutect2, varscan2
- LRRC66 | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs1164814700; called by muse, mutect2, varscan2
- LRRC9 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1175476030, COSV99580562; called by muse, mutect2, varscan2
- LRRC9 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758764289; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 77/260 reads (30%) | catalogued as rs747411092; called by mutect2, varscan2
- LRRN4CL | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 111/202 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294784510; called by muse, mutect2, varscan2
- LSAMP | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 162/367 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as rs1329182222, COSV100372744, COSV61300700; called by muse, mutect2, varscan2
- LSM4 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs764476513, COSV99416841; called by muse, mutect2, varscan2
- LSMEM2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782440636, COSV100269350; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs936902223; called by muse, mutect2, varscan2
- LY9 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139498658; called by muse, mutect2, varscan2
- MAD1L1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs371823704; called by muse, mutect2, varscan2
- MAGEL2 | c.1387del p.A463Lfs*2 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs1423747670; called by mutect2, varscan2
- MAP3K10 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs757704923; called by muse, mutect2, varscan2
- MAP3K3 | c.1094del p.G365Efs*42 | Frame Shift Del (DEL) | VAF 83/193 reads (43%) | catalogued as COSV62280848; called by mutect2, pindel, varscan2
- MAP4K5 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368497445, COSV50152507; called by muse, mutect2, varscan2
- MAP7D1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426629110, COSV60219033; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 81/211 reads (38%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MAST2 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.045); catalogued as rs368622066; called by muse, mutect2, varscan2
- MASTL | c.1372dup p.I458Nfs*5 | Frame Shift Ins (INS) | VAF 114/249 reads (46%) | catalogued as rs780698479; called by mutect2, varscan2
- MATN1 | c.85dup p.Q29Pfs*28 | Frame Shift Ins (INS) | VAF 46/131 reads (35%) | catalogued as rs1419789464; called by mutect2, pindel, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 32/61 reads (52%) | catalogued as rs767720617; called by mutect2, varscan2
- MBTPS1 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs756001167, COSV100597523; called by muse, mutect2, varscan2
- MCF2L | c.409C>T p.R137W (on ENST00000375608; = p.R105W on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368238188, COSV65051233; called by muse, mutect2, varscan2
- MECP2 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs1557134990; called by muse, mutect2, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 40/94 reads (43%) | catalogued as rs772983071; called by mutect2, varscan2
- MEGF11 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 83/253 reads (33%) | catalogued as COSV56562460; called by muse, varscan2
- MEGF11 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178836321; called by muse, varscan2
- MEIOC | c.2361del p.V788Yfs*12 | Frame Shift Del (DEL) | VAF 68/140 reads (49%) | catalogued as rs746201258; called by mutect2, varscan2
- MEMO1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs143148468; called by muse, mutect2, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs760012501; called by mutect2, varscan2
- MESP2 | c.718del p.V240Sfs*241 | Frame Shift Del (DEL) | VAF 89/227 reads (39%) | catalogued as rs756232049; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MGA | c.7469G>A p.R2490Q (on ENST00000219905 / NM_001164273.1; = p.R2281Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs774387775, COSV104376779; called by muse, mutect2, varscan2
- MICALL1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1190990003, COSV99317023; called by muse, mutect2, varscan2
- MIER2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 170/354 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); catalogued as rs762103363, COSV53397057; called by muse, mutect2, varscan2
- MINAR1 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 61/135 reads (45%) | catalogued as COSV100548719; called by muse, mutect2, varscan2
- MMP15 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 173/379 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs765310950, COSV54681293; called by muse, mutect2, varscan2
- MMP2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 127/284 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs375159741; called by muse, mutect2, varscan2
- MOGS | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431008691; called by muse, mutect2, varscan2
- MOV10 | c.2009A>G p.D670G | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV53518801; called by muse, mutect2, varscan2
- MPDZ | c.3106A>G p.I1036V | Missense Mutation (SNP) | VAF 142/285 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as rs1435912430; called by muse, mutect2, varscan2
- MPO | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as COSV56562649, COSV99034589; called by muse, mutect2, varscan2
- MPO | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 202/412 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs763622732; called by muse, mutect2, varscan2
- MRM1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756123716; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 61/187 reads (33%) | catalogued as rs1558718327, COSV62567684; called by mutect2, pindel, varscan2
- MRPL2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759643666; called by muse, mutect2, varscan2
- MRPL32 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as rs139835970; called by muse, mutect2, varscan2
- MRPS5 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 196/382 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1269130784; called by muse, mutect2, varscan2
- MTCL1 | c.5579A>G p.H1860R (on ENST00000306329 / NM_001378206.1; = p.H1541R on NM_015210.4) | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs923718876; called by muse, mutect2, varscan2
- MTRF1L | c.753del p.Q252Sfs*3 | Frame Shift Del (DEL) | VAF 79/210 reads (38%) | catalogued as rs762360173; called by mutect2, pindel, varscan2
- MUC16 | c.37855C>T p.R12619C | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs765697877, COSV67444013; called by muse, mutect2, varscan2
- MUC16 | c.10117G>A p.V3373I | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.096); catalogued as rs769634596; called by muse, mutect2, varscan2
- MUC3A | c.8594G>A p.R2865Q | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768338645, COSV60221474; called by muse, mutect2
- MXRA5 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759774377; called by muse, mutect2, varscan2
- MYBPC2 | c.2926del p.T976Pfs*76 | Frame Shift Del (DEL) | VAF 58/142 reads (41%) | catalogued as rs757263482; called by mutect2, pindel, varscan2
- MYBPC3 | c.2573G>T p.S858I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM087719; called by muse, mutect2
- MYH10 | c.5584C>T p.R1862C | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780650576, COSV52610206; called by muse, mutect2, varscan2
- MYH10 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs552031621, COSV52596701; called by muse, mutect2, varscan2
- MYLK | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 332/642 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs34542174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1C | c.2828C>T p.T943M (on ENST00000648651 / NM_001080779.2; = p.T908M on NM_033375.5) | Missense Mutation (SNP) | VAF 219/452 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs367849804; called by muse, mutect2, varscan2
- MYO1C | c.1123G>A p.A375T (on ENST00000648651 / NM_001080779.2; = p.A340T on NM_033375.5) | Missense Mutation (SNP) | VAF 254/500 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs780926824; called by muse, mutect2, varscan2
- MYO1C | c.740G>A p.G247D (on ENST00000648651 / NM_001080779.2; = p.G212D on NM_033375.5) | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759969887, COSV100704262, COSV62998764; called by muse, mutect2, varscan2
- MYT1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1042416220; called by muse, mutect2
- NAT16 | c.209_210insA p.I73Hfs*10 | Frame Shift Ins (INS) | VAF 164/658 reads (25%) | catalogued as COSV55865184; called by mutect2, pindel, varscan2
- NAV2 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1377815291; called by muse, mutect2, varscan2
- NCAPD3 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1213876164; called by muse, varscan2
- NCKAP1 | c.2551C>A p.L851I | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV62941633; called by muse, mutect2, varscan2
- NCKAP5 | c.5342G>A p.R1781H | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755560675; called by muse, mutect2, varscan2
- NCOR2 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs773358840, COSV62295973; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel
- NCOR2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs370196674; called by muse, mutect2, varscan2
- NDUFV1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 212/462 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs773211506; called by muse, mutect2, varscan2
- NELFE | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs772078692, COSV99064754; called by muse, mutect2, varscan2
- NES | c.2060A>C p.E687A | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100957788; called by muse, mutect2, varscan2
- NEUROD1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.104); catalogued as rs1390171738; called by muse, mutect2, varscan2
- NF1 | c.4958G>A p.R1653H (on ENST00000358273 / NM_001042492.3; = p.R1632H on NM_000267.3) | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs763413441, COSV55985392, COSV55985631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.2053G>A p.V685I (on ENST00000339876 / NM_001378329.1; = p.V681I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/331 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs771862901, COSV58357612; called by muse, mutect2, varscan2
- NFIX | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62175972; called by muse, mutect2, varscan2
- NFXL1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748118226; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 146/338 reads (43%) | catalogued as rs1171412241, CD054388; called by mutect2, varscan2
- NHLRC2 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65175797; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 51/163 reads (31%) | catalogued as rs111948120; called by pindel, varscan2
- NKAPL | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1228592352; called by muse, mutect2, varscan2
- NKX2-4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs924791828, COSV100698580; called by muse, mutect2, varscan2
- NLRP1 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 76/145 reads (52%) | catalogued as rs193920788, COSV52557794, COSV52567498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOBOX | c.1322dup p.L442Tfs*35 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs753934412; called by mutect2, varscan2
- NOD1 | c.1250G>A p.C417Y | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.135); catalogued as rs745564785; called by muse, mutect2
- NOL4 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 101/208 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs746220512, COSV52341252; called by muse, mutect2, varscan2
- NOS1 | c.3536A>G p.Y1179C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57619510; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH3 | c.6102dup p.G2035Rfs*60 | Frame Shift Ins (INS) | VAF 170/184 reads (92%) | catalogued as rs771517374; called by mutect2, varscan2
- NPAS3 | c.1000G>A p.V334I (on ENST00000356141 / NM_001164749.2; = p.V302I on NM_022123.3) | Missense Mutation (SNP) | VAF 118/225 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs777057923, COSV60824621; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 47/106 reads (44%) | catalogued as rs776154715; called by mutect2, varscan2
- NSG2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766024271, COSV57456632; called by muse, mutect2, varscan2
- NTSR2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs767804665; called by muse, mutect2, varscan2
- NWD1 | c.4177T>G p.C1393G | Missense Mutation (SNP) | VAF 162/384 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763989600; called by muse, mutect2, varscan2
- OBSCN | c.1604del p.P535Hfs*16 | Frame Shift Del (DEL) | VAF 66/177 reads (37%) | catalogued as COSV52744319; called by mutect2, pindel, varscan2
- OBSCN | c.3869C>T p.T1290M | Missense Mutation (SNP) | VAF 158/325 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs373940171; called by muse, mutect2, varscan2
- OBSL1 | c.458del p.G153Afs*105 | Frame Shift Del (DEL) | VAF 89/253 reads (35%) | catalogued as CX132462; called by mutect2, pindel, varscan2
- OCSTAMP | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as rs1262783199; called by muse, mutect2, varscan2
- OPN5 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373745956, COSV55246635; called by muse, mutect2, varscan2
- OR1C1 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as COSV68715537, COSV68716159; called by muse, mutect2, varscan2
- OR1M1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1177569351, COSV70036422; called by muse, mutect2, varscan2
- OR51T1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs768466143, COSV59023680; called by muse, mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- OR6C1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs979947032, COSV65573912; called by muse, mutect2, varscan2
- OR8B3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs755136502; called by mutect2, varscan2
- OR8S1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59599649; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs750679212; called by mutect2, varscan2
- OTOP3 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV60914507; called by muse, varscan2
- OTX1 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774184032; called by muse, mutect2, varscan2
- OXCT1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV52178940; called by muse, mutect2, varscan2
- PALM | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs1306293189; called by muse, mutect2, varscan2
- PAOX | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768196529, COSV53371654; called by muse, mutect2, varscan2
- PBRM1 | c.3427C>A p.P1143T (on ENST00000296302 / NM_001366071.2; = p.P1118T on NM_018313.5) | Missense Mutation (SNP) | VAF 164/311 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV56264350, COSV56280719; called by muse, mutect2, varscan2
- PCDH15 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 141/304 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57352641; called by muse, mutect2, varscan2
- PCDHA1 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as rs1554118218, COSV65373104; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 396/769 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56553142; called by muse, mutect2, varscan2
- PCDHA6 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV65350846, COSV65355737; called by muse, mutect2, varscan2
- PCDHA8 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.073); catalogued as COSV65335236, COSV65340588; called by muse, mutect2
- PCDHB1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554267179, COSV60631745, COSV60633356; called by muse, mutect2, varscan2
- PCDHB14 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 55/547 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as rs782732320, COSV53386946; called by muse, mutect2
- PCDHB4 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99078126; called by muse, mutect2, varscan2
- PCDHGA1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 96/193 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs781601310; called by muse, mutect2, varscan2
- PCDHGA6 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 88/197 reads (45%) | catalogued as rs1366674805, COSV53931781; called by muse, mutect2, varscan2
- PCDHGA6 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 224/431 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as rs181747779, COSV53986672; called by muse, mutect2, varscan2
- PCDHGB2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs575415323, COSV54013995; called by muse, mutect2, varscan2
- PCDHGB3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV53904567; called by muse, mutect2, varscan2
- PCDHGB4 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 185/380 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs771332132; called by muse, mutect2, varscan2
- PCDHGB6 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 172/312 reads (55%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.473); catalogued as COSV53901987; called by muse, varscan2
- PCM1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758246567, COSV100279438; called by muse, mutect2, varscan2
- PCNT | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 239/494 reads (48%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1440769686; called by muse, mutect2, varscan2
- PDILT | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 165/382 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100199885; called by muse, mutect2, varscan2
- PDZD2 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 178/321 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs577368144; called by muse, mutect2, varscan2
- PGR | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV54798727; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 69/185 reads (37%) | catalogued as rs749326031; called by pindel, varscan2
- PHKG2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 179/373 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779515173, COSV60313653; called by muse, mutect2, varscan2
- PHLDA3 | c.265dup p.L89Pfs*? (on ENST00000367309; = p.L89Pfs*138 on NM_012396.5) | Frame Shift Ins (INS) | VAF 152/401 reads (38%) | catalogued as rs1245629568; called by mutect2, pindel, varscan2
- PHLDB1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 36/485 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs191697288, COSV61876790; called by muse, mutect2
- PHLDB1 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782328887; called by muse, mutect2, varscan2
- PIEZO2 | c.5395G>A p.V1799M | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1404474119; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 39/99 reads (39%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PKD1 | c.6526C>T p.R2176C | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746489969; called by muse, mutect2, varscan2
- PKD1 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs756501602; called by muse, mutect2
- PKD1L1 | c.1672del p.R558Dfs*10 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs897900295; called by mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel, varscan2
- PLAGL1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1187230713; called by muse, mutect2, varscan2
- PLB1 | c.4081G>A p.A1361T | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749695328, COSV59832429; called by muse, mutect2, varscan2
- PLEC | c.5930C>T p.A1977V (on ENST00000322810 / NM_201380.4; = p.A1867V on NM_000445.5) | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100518140; called by muse, mutect2, varscan2
- PLEKHA6 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs529169780; called by muse, mutect2, varscan2
- PLEKHN1 | c.1901A>G p.H634R (on ENST00000379409; = p.H582R on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.106); catalogued as COSV58021280; called by muse, mutect2, varscan2
- PLK1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1379177197, COSV55622956; called by muse, mutect2, varscan2
- PLXNA2 | c.1393dup p.H465Pfs*27 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs752105673; called by mutect2, varscan2
- PLXNB3 | c.4963dup p.V1655Gfs*76 | Frame Shift Ins (INS) | VAF 31/36 reads (86%) | catalogued as rs782076287; called by mutect2, varscan2
- PNPLA6 | c.1985G>A p.R662H (on ENST00000414982 / NM_001166111.2; = p.R614H on NM_006702.5) | Missense Mutation (SNP) | VAF 170/343 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1489744966, COSV55375843; called by muse, mutect2, varscan2
- PNPLA6 | c.2416G>A p.A806T (on ENST00000414982 / NM_001166111.2; = p.A758T on NM_006702.5) | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs144206674; called by muse, mutect2, varscan2
- PNPLA6 | c.2470C>T p.R824C (on ENST00000414982 / NM_001166111.2; = p.R776C on NM_006702.5) | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs531445564, COSV55375072; called by muse, mutect2, varscan2
- POLK | c.507del p.N170Tfs*8 | Frame Shift Del (DEL) | VAF 127/336 reads (38%) | catalogued as rs758745741; called by mutect2, pindel, varscan2
- POLR1A | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777068250; called by muse, mutect2, varscan2
- POTEA | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.148); catalogued as rs1231215026; called by muse, mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 180/853 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, mutect2, varscan2
- POTEG | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 357/2422 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.975); catalogued as rs376547042, COSV73631102; called by muse, mutect2, varscan2
- POU4F2 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV55582926; called by muse, mutect2, varscan2
- PPARGC1B | c.2199G>T p.Q733H | Missense Mutation (SNP) | VAF 163/334 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58528498; called by muse, mutect2, varscan2
- PPIL2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 68/115 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs561147309, COSV58605424; called by muse, mutect2, varscan2
- PPL | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560350086, COSV52167771; called by muse, mutect2, varscan2
- PPL | c.1362dup p.T455Hfs*4 | Frame Shift Ins (INS) | VAF 58/104 reads (56%) | catalogued as rs753902804; called by mutect2, varscan2
- PPM1N | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763921031; called by muse, mutect2, varscan2
- PPP2R5D | c.36del p.K13Rfs*94 | Frame Shift Del (DEL) | VAF 68/159 reads (43%) | catalogued as COSV57840074; called by mutect2, pindel, varscan2
- PRAMEF10 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1356419826; called by muse, mutect2, varscan2
- PRAMEF17 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 248/567 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs1173726239; called by muse, mutect2, varscan2
- PRDM16 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772868294, COSV54611602; called by muse, mutect2, varscan2
- PRDM16 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs753949982; called by muse, mutect2, varscan2
- PRDM7 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 177/377 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV57987772; called by muse, mutect2, varscan2
- PREX1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs1381418200, COSV64254516; called by muse, mutect2, varscan2
- PRG4 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100798145; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 37/94 reads (39%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 154/250 reads (62%) | catalogued as rs764069617; called by mutect2, varscan2
- PRKCQ | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370703516, COSV54105311; called by muse, mutect2, varscan2
- PRKRIP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 97/348 reads (28%) | catalogued as rs782018191; called by muse, mutect2, varscan2
- PRR14 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54912027; called by muse, mutect2, varscan2
- PRR16 | c.320del p.P107Qfs*11 (on ENST00000407149 / NM_001300783.2; = p.P84Qfs*11 on NM_016644.2) | Frame Shift Del (DEL) | VAF 67/181 reads (37%) | catalogued as rs1371403180; called by mutect2, pindel, varscan2
- PRR23A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs765076882, COSV67214626, COSV67214848; called by muse, mutect2, varscan2
- PRR32 | c.675G>A p.W225* | Nonsense Mutation (SNP) | VAF 96/96 reads (100%) | catalogued as COSV64420464; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 58/135 reads (43%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSD | c.676del p.R226Gfs*68 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs772089836; called by mutect2, pindel, varscan2
- PSG8 | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764813765, COSV60610556; called by muse, mutect2, varscan2
- PTCD3 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 100/206 reads (49%) | catalogued as rs1468225992; called by muse, mutect2, varscan2
- PTPN12 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.1); catalogued as rs977073067; called by muse, mutect2, varscan2
- PTPRCAP | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV57055486; called by muse, mutect2, varscan2
- PUM1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.267); catalogued as rs752999527; called by muse, mutect2, varscan2
- PWWP3B | c.916del p.A306Lfs*29 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | catalogued as COSV100531264; called by mutect2, pindel, varscan2
- PXMP4 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 192/383 reads (50%) | catalogued as rs201904586, COSV54133033; called by muse, mutect2, varscan2
- R3HDM1 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 142/319 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51526518; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | catalogued as rs745353960; called by mutect2, varscan2
- RAD51B | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 200/410 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1171289062; called by muse, mutect2, varscan2
- RANBP17 | c.1884del p.K628Nfs*3 | Frame Shift Del (DEL) | VAF 45/124 reads (36%) | catalogued as COSV101206115; called by mutect2, pindel, varscan2
- RASGEF1A | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs776561636, COSV65666808; called by muse, mutect2, varscan2
- RASIP1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1314307287, COSV55802765; called by muse, mutect2, varscan2
- RASL10A | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs912333096; called by muse, mutect2, varscan2
- RB1CC1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 89/214 reads (42%) | catalogued as rs1563437586, COSV50258374; called by muse, mutect2, varscan2
- RBM14 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs930621157; called by muse, mutect2, varscan2
- RCC1L | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 207/368 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781822837; called by muse, mutect2, varscan2
- REG1A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777579151, COSV52071733, COSV52072168; called by muse, mutect2
- REG3A | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 77/160 reads (48%) | catalogued as COSV59409239; called by muse, mutect2, varscan2
- REPIN1 | c.1116dup p.S373Lfs*228 | Frame Shift Ins (INS) | VAF 24/113 reads (21%) | catalogued as rs759247453; called by mutect2, varscan2
- REV3L | c.4211G>A p.R1404H | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs985550312, COSV100725342; called by muse, mutect2, varscan2
- REXO1 | c.2959C>A p.R987S | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV50079710; called by muse, mutect2, varscan2
- RFPL1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585862; called by muse, mutect2, varscan2
- RFX6 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60584144; called by muse, mutect2, varscan2
- RFX7 | c.992G>A p.R331H (on ENST00000559447 / NM_001368074.1; = p.R428H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1315506077, COSV57966272; called by muse, mutect2, varscan2
- RFXAP | c.359del p.G120Afs*18 | Frame Shift Del (DEL) | VAF 120/184 reads (65%) | catalogued as rs1224857205; called by mutect2, varscan2
- RGL2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as rs778787902; called by muse, mutect2, varscan2
- RGL4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1467976178; called by muse, mutect2, varscan2
- RHBDF1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 111/197 reads (56%) | catalogued as rs761693781, COSV51953896; called by muse, mutect2, varscan2
- RIC8A | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 122/273 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs772146366; called by muse, mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 70/174 reads (40%) | catalogued as COSV54616696; called by mutect2, pindel, varscan2
- RIF1 | c.3640C>A p.P1214T | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99689849; called by muse, mutect2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RNF167 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs760638375, COSV99337215; called by muse, mutect2, varscan2
- RNF217 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs777176681; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO4 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100127172; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 57/150 reads (38%) | catalogued as rs1392239785; called by mutect2, pindel, varscan2
- RPRD1B | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs200179296, COSV65033071, COSV65033831; called by muse, mutect2, varscan2
- RPS2 | c.30dup p.P11Afs*48 | Frame Shift Ins (INS) | VAF 28/70 reads (40%) | catalogued as rs757493536; called by mutect2, varscan2
- RPTOR | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60816058; called by muse, mutect2, varscan2
- RRAGC | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1327011466; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- RTN4RL2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 51/472 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); catalogued as rs200131252; called by muse, mutect2, varscan2
- RUFY1 | c.1957_1959del p.K653del | In Frame Del (DEL) | VAF 107/255 reads (42%) | catalogued as rs777382030; called by mutect2, pindel, varscan2
- RUFY2 | c.1543A>C p.I515L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56258621; called by muse, mutect2, varscan2
- RUFY4 | c.1100del p.G367Afs*31 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV60246042; called by mutect2, varscan2
- RUSC2 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs188737758; called by muse, mutect2, varscan2
- RYR2 | c.1614G>A p.A538= | Splice Region (SNP) | VAF 53/120 reads (44%) | catalogued as rs566885717, COSV63688605; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SAFB2 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs755798347, COSV53040566; called by muse, mutect2, varscan2
- SAFB2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766256654; called by muse, mutect2, varscan2
- SBF1 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs767810845; called by muse, mutect2, varscan2
- SBNO1 | c.3905G>A p.R1302H (on ENST00000420886; = p.R1301H on NM_018183.5) | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV57347449; called by muse, mutect2, varscan2
- SCAPER | c.2613dup p.A872Sfs*13 | Frame Shift Ins (INS) | VAF 62/168 reads (37%) | catalogued as rs757259031; called by mutect2, varscan2
- SCART1 | c.2276-5C>T | Splice Region (SNP) | VAF 91/252 reads (36%) | catalogued as rs770031852; called by muse, varscan2
- SCML4 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs769590136, COSV64636916; called by muse, mutect2, varscan2
- SCN10A | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778131235, COSV71861217, COSV71862603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.5689C>T p.R1897W (on ENST00000333535 / NM_198056.3; = p.R1896W on NM_000335.5) | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs45465995, CM097690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.5408_5409del p.S1803* (on ENST00000303354; = p.S1792* on NM_002977.3) | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | catalogued as rs945489250; called by pindel, varscan2
- SCYL1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs573462705; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 47/107 reads (44%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEMA5A | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 221/485 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1436765433, COSV66793308; called by muse, mutect2, varscan2
- SEMA6B | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 159/320 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1279041694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs1184198853; called by muse, mutect2, varscan2
- SEPTIN2 | c.129C>T p.V43= | Splice Region (SNP) | VAF 38/88 reads (43%) | catalogued as rs779757638, COSV63471991; called by muse, mutect2, varscan2
- SERPINA4 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs770272743; called by muse, mutect2, varscan2
- SETDB1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs144623268; called by muse, mutect2, varscan2
- SETX | c.7330C>T p.R2444C | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372535542, CM087874; ClinVar: uncertain significance; called by muse, varscan2
- SETX | c.7322C>A p.A2441D | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56395660; called by muse, varscan2
- SH2D3C | c.826G>A p.E276K (on ENST00000314830 / NM_170600.3; = p.E119K on NM_005489.4) | Missense Mutation (SNP) | VAF 257/583 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs570813230, COSV100136432; called by muse, mutect2, varscan2
- SH3PXD2A | c.2587G>A p.A863T (on ENST00000369774 / NM_001365079.1; = p.A835T on NM_014631.2) | Missense Mutation (SNP) | VAF 160/394 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs766798828, COSV60116246; called by muse, mutect2, varscan2
- SHANK1 | c.5435C>T p.A1812V | Missense Mutation (SNP) | VAF 156/296 reads (53%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.151); catalogued as rs749037124, COSV53255448; called by muse, mutect2, varscan2
- SHANK1 | c.4587del p.S1530Pfs*95 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as COSV53262336; called by mutect2, pindel, varscan2
- SHARPIN | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs539568406; called by muse, mutect2, varscan2
- SI | c.3593dup p.L1198Ffs*14 | Frame Shift Ins (INS) | VAF 136/330 reads (41%) | catalogued as rs1222601003; called by mutect2, pindel, varscan2
- SIN3B | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.053); catalogued as COSV56136185; called by muse, mutect2
- SIPA1L3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs754702591, COSV99730199; called by muse, mutect2, varscan2
- SLC13A5 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 105/226 reads (46%) | catalogued as COSV99545937; called by muse, mutect2, varscan2
- SLC15A1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 166/245 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs771067175, COSV64731790; called by muse, mutect2, varscan2
- SLC16A14 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1205196087, COSV54617922; called by muse, mutect2, varscan2
- SLC22A6 | c.777dup p.A260Cfs*11 | Frame Shift Ins (INS) | VAF 106/218 reads (49%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC23A1 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 147/285 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs756842191; called by muse, mutect2, varscan2
- SLC25A47 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1248512079; called by muse, mutect2, varscan2
- SLC26A5 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 208/618 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV59706746; called by muse, mutect2, varscan2
- SLC35A5 | c.898del p.Y300Mfs*8 | Frame Shift Del (DEL) | VAF 76/213 reads (36%) | catalogued as rs1363537717; called by mutect2, pindel, varscan2
- SLC40A1 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs564905172, COSV53724741; called by muse, mutect2, varscan2
- SLC47A2 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs751597777, COSV100328164; called by muse, mutect2, varscan2
- SLC4A5 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1553452434, COSV61030120; called by muse, mutect2, varscan2
- SLC5A11 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs552396984; called by muse, mutect2, varscan2
- SLC9A7 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs375953952, COSV60378801; called by muse, mutect2, varscan2
- SLIT2 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.445); catalogued as COSV56561123, COSV99888209; called by muse, mutect2, varscan2
- SLITRK5 | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs756482226; called by muse, mutect2, varscan2
- SLX4 | c.5080G>A p.A1694T | Missense Mutation (SNP) | VAF 221/448 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs1218491919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 48/111 reads (43%) | catalogued as rs1461272768, COSV57645914; called by mutect2, varscan2
- SNED1 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs779036938, COSV60026747; called by muse, mutect2, varscan2
- SNIP1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1478911110; called by muse, mutect2, varscan2
- SNRNP70 | c.46del p.R16Vfs*95 | Frame Shift Del (DEL) | VAF 68/164 reads (41%) | catalogued as rs1183371144; called by mutect2, pindel, varscan2
- SNTB2 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs375616677; called by muse, mutect2, varscan2
- SNX20 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100319294; called by muse, mutect2, varscan2
- SOCS6 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV67547192; called by muse, mutect2, varscan2
- SORCS2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs779383513, COSV100214076; called by muse, mutect2, varscan2
- SOX13 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs762506053, COSV65826750; called by muse, mutect2, varscan2
- SP3 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100022144; called by muse, mutect2, varscan2
- SPAG6 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs749967665, COSV57624170; called by muse, mutect2, varscan2
- SPATA20 | c.1195G>A p.A399T (on ENST00000356488 / NM_001258372.1; = p.A415T on NM_022827.4) | Missense Mutation (SNP) | VAF 196/419 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs374270120; called by muse, mutect2, varscan2
- SPATA20 | c.1683del p.T562Lfs*73 (on ENST00000356488 / NM_001258372.1; = p.T578Lfs*73 on NM_022827.4) | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs748942419; called by mutect2, pindel, varscan2
- SPATA31D1 | c.2417A>G p.E806G | Missense Mutation (SNP) | VAF 202/438 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as rs992271271, COSV61192820; called by muse, mutect2
- SPATA7 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs775594191; called by muse, mutect2, varscan2
- SPEF2 | c.700del p.M234* | Frame Shift Del (DEL) | VAF 89/230 reads (39%) | catalogued as rs528892977; called by mutect2, pindel, varscan2
- SPEG | c.9742C>T p.R3248C | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs1357626784; called by muse, mutect2, varscan2
- SPEN | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); catalogued as rs745325343; called by muse, mutect2, varscan2
- SPEN | c.8668G>A p.A2890T | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs768779200; called by muse, mutect2, varscan2
- SPOUT1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1340581066; called by muse, mutect2, varscan2
- SPP2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs201489523; called by muse, mutect2, varscan2
- SPRR2E | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV64203994, COSV64204055; called by muse, mutect2, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 54/101 reads (53%) | catalogued as rs567805129; called by mutect2, varscan2
- SPRY4 | c.761C>T p.A254V (on ENST00000434127 / NM_001127496.3; = p.A277V on NM_030964.4) | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59986255; called by muse, mutect2, varscan2
- SPTA1 | c.1584G>T p.Q528H | Missense Mutation (SNP) | VAF 193/422 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV63750507; called by muse, mutect2, varscan2
- SRCAP | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760183638, COSV99349532; called by muse, mutect2, varscan2
- SRD5A1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs545726471, COSV57014616; called by muse, mutect2, varscan2
- SREBF1 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 148/285 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs761664089; called by muse, mutect2, varscan2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs760883618; called by pindel, varscan2
- STIMATE | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1276988897; called by muse, mutect2, varscan2
- STX1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs782606855; called by muse, mutect2, varscan2
- SUCLG2 | c.1316del p.L439Yfs*8 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs757697438; called by mutect2, pindel
- SUGP1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1486997637; called by muse, mutect2, varscan2
- SULT1A1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 125/263 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs752498609; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT20HL1 | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs866999802; called by muse, varscan2
1,912 further variants in this file (1,049 protein-altering or splice-affecting, 503 silent, 360 other) are not listed here.
